Gene-level copy-number profile of tumor specimen TCGA-BR-A4PF-01A from TCGA case TCGA-BR-A4PF, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 72.3 years (26,412 days).
Specimen TCGA-BR-A4PF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.6c08c781-70d8-43ba-aa9e-f24ba64bebb7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4PF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce0c1089-a366-4c35-95d6-61b9c8a97bf9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 888; copy number 2: 32,697; copy number 3: 15,883; copy number 4: 8,312; copy number 5: 917; copy number 6: 267; copy number 7: 32; copy number 8: 51; copy number 9: 27; copy number 10: 147; copy number 11: 1; copy number 12: 70; copy number 13: 21; copy number 15: 147; copy number 16: 53; copy number 17: 100; copy number 19: 17; copy number 21: 68; copy number 28: 119.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4PF-01A-11D-A253-01): tumor purity 0.5, ploidy 2.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,037 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:192,629,919–201,229,406, 127 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:160,438,594–162,162,977, 14 genes, copy number 5 (within-gene range 3–5): MIR3142HG, MIR3142, MIR146A, ATP10B, AC008456.1, AC011363.1, LINC02159, GABRB2, GABRA6, AC091944.1, GLRXP3, GABRA1, LINC01202, GABRG2.
- chr5:162,477,891–162,762,313, 2 genes, copy number 5: RNU6-164P, ARL2BPP5.
- chr7:91,264,433–94,834,447, 67 genes, copy number 7–16 (broad region; genes not listed).
- chr7:95,018,163–95,018,554, 2 genes, copy number 7: HINT1P2, AC002429.1.
- chr7:96,481,626–101,314,800, 188 genes, copy number 8–19 (broad region; genes not listed).
- chr11:8,106,056–16,739,591, 154 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:66,842,835–67,425,607, 27 genes, copy number 9: RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860, RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D, SSH3, AP001885.2, RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1.
- chr11:68,980,021–70,385,312, 45 genes, copy number 12 (within-gene range 2–12): MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2.
- chr11:77,216,558–78,079,865, 24 genes, copy number 12 (within-gene range 2–12): GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1.
- chr12:14,914,039–37,576,384, 331 genes, copy number 6–28 (broad region; genes not listed).
- chr12:55,752,463–55,827,546, 2 genes, copy number 13 (within-gene range 3–13): SARNP, AC023055.1.
- chr12:55,818,041–60,419,293, 172 genes, copy number 5–17 (broad region; genes not listed).
- chr12:63,271,404–70,243,379, 161 genes, copy number 10–15 (within-gene range 2–15) (broad region; genes not listed).
- chr18:29,278,509–80,247,514, 721 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
